Somatic mutation profile of tumor specimen 0DVXF9 from CCDI case PBCNFN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 8.6 years (3,123 days).
Specimen 0DVXF9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7f229ce-d54a-41fd-9dd8-e0b097263d1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94b328ca-7fab-4e44-9595-6a3ca076ba02

The open-access MAF lists 21 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 8, Missense Mutation 5, Nonsense Mutation 3, 3'UTR 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 92/582 reads (16%) | catalogued as rs5030730, CM100263, CS002446, COSV63740877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- CFAP54 | c.8943G>T p.W2981C | Missense Mutation (SNP) | VAF 125/767 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ERVMER34-1 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 22/324 reads (7%) | called by mutect2, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 67/670 reads (10%) | called by muse, varscan2
- PRR35 | c.222G>C p.W74C | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TNFAIP2 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GPR42 | c.141G>A p.P47= | Silent (SNP) | VAF 74/257 reads (29%) | catalogued as rs1179960648; called by muse, mutect2, varscan2
- WDR45 | c.369C>T p.I123= (on ENST00000376372 / NM_001029896.2; = p.I124= on NM_007075.3) | Silent (SNP) | VAF 70/263 reads (27%) | catalogued as rs1557084257; called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- ARNT2 | c.622+84T>C | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CEP295 | c.5948-63T>G | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- CTSC | c.318+6725T>G | Intron (SNP) | VAF 19/203 reads (9%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, varscan2
- HNRNPUL2 | c.*53A>T | 3'UTR (SNP) | VAF 8/73 reads (11%) | catalogued as rs1250707384; called by mutect2, varscan2
- ITSN1 | c.*54G>A | 3'UTR (SNP) | VAF 75/150 reads (50%) | catalogued as rs1351580611; called by muse, mutect2, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- NLN | c.559-56G>A | Intron (SNP) | VAF 11/110 reads (10%) | catalogued as rs530368281; called by mutect2, varscan2
- TNFSF10 | c.418+17_418+20del | Intron (DEL) | VAF 60/221 reads (27%) | called by mutect2, varscan2
